Gene-level copy-number profile of tumor specimen TCGA-CH-5762-01A from TCGA case TCGA-CH-5762, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.4 years (22,068 days).
Specimen TCGA-CH-5762-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.b5f6e1b9-7de0-464f-8735-542e27a90b71.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CH-5762-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 399 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/701e185c-53d2-402f-9f48-4c6690f0de92

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,387; copy number 1: 3,237; copy number 2: 48,851; copy number 3: 5,230; copy number 4: 460; copy number 5: 53; copy number 9: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CH-5762-01A-11D-1574-01): tumor purity 0.34, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:97,737,894–97,738,913, 1 gene: AC112203.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 59 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:87,944,885–88,602,195, 12 genes, copy number 5: RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1, TMTC3, Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1.
- chr12:89,027,757–89,028,522, 1 gene, copy number 5: AC006199.1.
- chr12:89,319,364–90,112,779, 22 genes, copy number 5: MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1, POC1B, CENPCP1, POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2, AC025034.1, ATP2B1, ATP2B1-AS1, AC009522.1, RNA5SP365, MRPL2P1, RNU6-148P, BRWD1P2, LINC02399, AC126178.1.
- chr12:93,003,415–93,215,679, 1 gene, copy number 5 (within-gene range 4–5): AC138123.1.
- chr12:93,090,480–93,894,840, 17 genes, copy number 5 (within-gene range 4–5): AC138123.2, NACAP8, LINC02412, AC126172.1, AC124947.2, AC124947.1, NUDT4, UBE2N, Y_RNA, MRPL42, RN7SL737P, AC025260.1, SOCS2-AS1, SOCS2, AC012085.1, CRADD, AC012085.2.
- chr17:46,029,916–46,225,389, 1 gene, copy number 9 (within-gene range 2–9): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 9: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.

Autosomal genes at a single copy (total copy number 1): 3,237. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
